Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOL, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AAOL-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATH []

Order Dr:

Order Clinic:

Order Dx: PRELIM: LEFT TESTES TUMOR

Specimen Source: L TESTIS

CASE NO.:

GROSS EXAM DATE:

PHYSICIAN & PAGER #:

-- CONCLUSION/DIAGNOSTIC CODE

NON-ROUTINE

-- REPORT

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA WITH EXTENSIVE NECROSIS (13 X 8 X 7 CM), left testis, radical orchiectomy (see note).
2. LYMPHOVASCULAR INVASION NOT IDENTIFIED.
3. TUMOR LIMITED TO TESTIS.
4. MARGINS FREE OF TUMOR.
5. pT1NXMX.

ICD-O-3

Seminoma NOS 9061/3

Site @ Testis NOS

C62.9

Note: Epididymis is not identified.

GROSS DESCRIPTION:

Q2 3/21/14

The specimen is received fresh and is labeled with the patient's name, , and "left testis and spermatic cord." It consists of a 540

gram orchiectomy specimen including a 13 x 8 x 7-cm testes, and 9 x 2.2-cm spermatic cord. The whole testis is filled with a tan-white to tan-pink fleshy, variegated, soft, and friable mass. Close to the spermatic cord is a 4.5 x 4.3-cm and tan-brown necrotic area that is well circumscribed. The spermatic cord is unremarkable. No normal testicular tissue could be identified. Representative cross-sections are embedded. R11. Cassette summary: #1 to 3 - Spermatic cord. #4 through 11 - Tumor (cassette #9 has a tan-yellow area in the tumor, #11).

[page 2 of 2]
-- REPORT --

Source: NCI Genomic Data Commons file 4d9ad422-c619-42e9-aa06-4be16517ace8 (TCGA-XE-AAOL.86B70390-C198-4561-B741-C2DC50673163.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).